Somatic mutation profile of tumor specimen 0DX7FV from CCDI case PBCRCW, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Brain stem; Age at diagnosis: 5.6 years (2,062 days).
Specimen 0DX7FV: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 72bac02f-8224-4a24-8182-390897a64440.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DX7EY (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d456f3bd-62d6-4242-bb69-7048f66099ed

The open-access MAF lists 32 somatic variants for this specimen: 24 protein-altering or splice-affecting, 5 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 21, Silent 5, 5'UTR 2, Frame Shift Del 2, Nonsense Mutation 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- H3-3A | c.83A>T p.K28M | Missense Mutation (SNP) | VAF 207/883 reads (23%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.697); catalogued as rs1057519903, COSV64731746, COSV64731769; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 315/350 reads (90%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ADCY4 | c.946C>T p.R316W | Missense Mutation (SNP) | VAF 619/1178 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1371931557, COSV60258080; called by muse, mutect2, varscan2
- CNGB3 | c.1627G>T p.V543F | Missense Mutation (SNP) | VAF 109/1682 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.713); catalogued as rs746817996, COSV100181307, COSV60687692; called by muse, mutect2
- GOLGA6L4 | c.797A>T p.E266V | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.331); catalogued as rs1329023028; called by muse, varscan2
- IQCA1 | c.937G>A p.G313R | Missense Mutation (SNP) | VAF 54/1052 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs183422881; called by muse, mutect2
- OR2T11 | c.427G>T p.A143S | Missense Mutation (SNP) | VAF 95/919 reads (10%) | SIFT tolerated (0.89); PolyPhen benign (0.077); catalogued as rs755765980; called by muse, mutect2, varscan2
- OR5D14 | c.202C>A p.L68I | Missense Mutation (SNP) | VAF 47/969 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV59458072; called by muse, mutect2
- PPP4R3C | c.43G>A p.E15K | Missense Mutation (SNP) | VAF 117/559 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.281); catalogued as rs1204846158; called by muse, mutect2, varscan2
- SLCO4C1 | c.1811G>T p.R604M | Missense Mutation (SNP) | VAF 76/595 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100196045; called by mutect2, varscan2
- TNIP1 | c.435G>C p.M145I | Missense Mutation (SNP) | VAF 23/811 reads (3%) | SIFT tolerated (0.13); PolyPhen benign (0.023); catalogued as COSV100161233; called by muse, mutect2
- WNK4 | c.2111G>A p.R704Q | Missense Mutation (SNP) | VAF 73/879 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.048); catalogued as rs150554297; called by muse, mutect2
- ASNS | c.1117G>T p.G373C | Missense Mutation (SNP) | VAF 165/1094 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COPB2 | c.814G>C p.E272Q | Missense Mutation (SNP) | VAF 110/1054 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.692); called by muse, varscan2
- CPS1 | c.452A>C p.Q151P | Missense Mutation (SNP) | VAF 191/1560 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.097); called by muse, mutect2, varscan2
- DUSP12 | c.673A>T p.R225W | Missense Mutation (SNP) | VAF 72/968 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- FGF23 | c.523C>T p.R175W | Missense Mutation (SNP) | VAF 101/1057 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.798); called by muse, mutect2
- GAS2L3 | c.494G>C p.G165A | Missense Mutation (SNP) | VAF 521/1161 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.584); called by muse, mutect2, varscan2
- GOLGA6L10 | c.219C>G p.I73M | Missense Mutation (SNP) | VAF 37/711 reads (5%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.86); called by muse, mutect2
- MUC5AC | c.11797A>G p.T3933A | Missense Mutation (SNP) | VAF 25/617 reads (4%) | SIFT tolerated (0.9); called by muse, mutect2
- MYH4 | c.2607G>C p.K869N | Missense Mutation (SNP) | VAF 156/929 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- NF1 | c.6533del p.F2178Sfs*22 (on ENST00000358273 / NM_001042492.3; = p.F2157Sfs*22 on NM_000267.3) | Frame Shift Del (DEL) | VAF 658/1653 reads (40%) | called by mutect2, pindel, varscan2
- ODF4 | c.380C>G p.S127* | Nonsense Mutation (SNP) | VAF 80/435 reads (18%) | called by muse, mutect2, varscan2
- RPS6KA6 | c.1080del p.F360Lfs*56 | Frame Shift Del (DEL) | VAF 339/971 reads (35%) | called by mutect2, pindel, varscan2
- CACNB2 | c.1362C>T p.A454= (on ENST00000324631 / NM_201596.3; = p.A399= on NM_000724.4) | Silent (SNP) | VAF 90/430 reads (21%) | catalogued as rs769870567; called by muse, mutect2, varscan2
- GDPD5 | c.1695C>T p.S565= | Silent (SNP) | VAF 84/704 reads (12%) | catalogued as rs537176106; called by muse, mutect2, varscan2
- RUVBL2 | c.102C>T p.D34= | Silent (SNP) | VAF 46/570 reads (8%) | catalogued as rs200990353; called by muse, mutect2
- STON1-GTF2A1L | c.2982C>T p.H994= | Silent (SNP) | VAF 40/1214 reads (3%) | called by muse, mutect2
- TRPM5 | c.3024C>T p.P1008= | Silent (SNP) | VAF 331/495 reads (67%) | catalogued as rs760152144; called by muse, mutect2, varscan2
- PDLIM1P2 | chr17:21440239 T>A | 3'Flank (SNP) | VAF 93/262 reads (35%) | called by muse, mutect2, varscan2
- S1PR3 | c.-302C>G | 5'UTR (SNP) | VAF 212/243 reads (87%) | called by muse, mutect2, varscan2
- SPESP1 | c.-65G>C | 5'UTR (SNP) | VAF 37/109 reads (34%) | called by muse, mutect2, varscan2
